Somatic mutation profile of tumor specimen C3N-00832-01 (aliquot CPT0078800009) from CPTAC case C3N-00832, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 79.2 years (28,920 days).
Specimen C3N-00832-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 819b6c07-a7a4-4fdd-9349-e549e5ec21a8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00832-31 (Blood Derived Normal), aliquot CPT0078820002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2a964588-1e8a-458c-8a47-ebb4a7f55094

The open-access MAF lists 82 somatic variants for this specimen: 62 protein-altering or splice-affecting, 12 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 50, Silent 12, Frame Shift Del 7, Intron 4, Nonsense Mutation 4, 3'UTR 3, Splice Site 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.70G>C p.D24H | Missense Mutation (SNP) | VAF 284/433 reads (66%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.684); catalogued as rs786201995, CM110141, CM993669, COSV64288588, COSV64289716, COSV64295411; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ANXA4 | c.346G>C p.A116P | Missense Mutation (SNP) | VAF 62/225 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV67849288; called by muse, mutect2, varscan2
- DNAH6 | c.11512A>C p.I3838L | Missense Mutation (SNP) | VAF 48/124 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0.163); catalogued as rs1017465801; called by muse, mutect2, varscan2
- DYRK3 | c.1192A>G p.I398V | Missense Mutation (SNP) | VAF 95/248 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs144725167, COSV65606986; called by muse, mutect2, varscan2
- FAM114A2 | c.1249C>G p.L417V | Missense Mutation (SNP) | VAF 58/176 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs201640396; called by muse, varscan2
- GRM5 | c.3131C>T p.S1044L (on ENST00000305447 / NM_001143831.2; = p.S1012L on NM_000842.4) | Missense Mutation (SNP) | VAF 37/243 reads (15%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.083); catalogued as rs1433808039; called by muse, mutect2, varscan2
- NOTCH3 | c.5798A>G p.N1933S | Missense Mutation (SNP) | VAF 20/339 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs572615224, COSV54643532; called by muse, mutect2
- PIK3CD | c.2113A>C p.K705Q | Missense Mutation (SNP) | VAF 167/562 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV63132054; called by muse, mutect2, varscan2
- PPCS | c.547G>T p.D183Y | Missense Mutation (SNP) | VAF 58/179 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100999494; called by muse, mutect2, varscan2
- SDK2 | c.2921A>T p.K974M | Missense Mutation (SNP) | VAF 51/168 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.162); catalogued as COSV66184395; called by muse, mutect2, varscan2
- SLX4 | c.1828C>G p.Q610E | Missense Mutation (SNP) | VAF 51/337 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1485275546; called by muse, mutect2, varscan2
- SON | c.1379C>G p.S460C | Missense Mutation (SNP) | VAF 77/223 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.784); catalogued as COSV51653081; called by muse, mutect2, varscan2
- STARD9 | c.6241G>T p.D2081Y | Missense Mutation (SNP) | VAF 55/197 reads (28%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.611); catalogued as COSV104392742; called by muse, mutect2, varscan2
- TATDN2 | c.736G>A p.A246T | Missense Mutation (SNP) | VAF 155/549 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.026); catalogued as rs1408447599; called by muse, mutect2, varscan2
- ZNF554 | c.341C>T p.S114L | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV57887421; called by muse, mutect2, varscan2
- AC231657.3 | c.644C>G p.A215G | Missense Mutation (SNP) | VAF 90/138 reads (65%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADAR | c.3548G>C p.G1183A | Missense Mutation (SNP) | VAF 167/509 reads (33%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADCY5 | c.647T>A p.F216Y | Missense Mutation (SNP) | VAF 35/81 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- ADH1A | c.719A>T p.E240V | Missense Mutation (SNP) | VAF 115/440 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- ANXA5 | c.577A>T p.K193* | Nonsense Mutation (SNP) | VAF 45/189 reads (24%) | called by muse, mutect2, varscan2
- B3GNT4 | c.334T>G p.S112A | Missense Mutation (SNP) | VAF 72/217 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, varscan2
- BRD7 | c.1494A>T p.E498D | Missense Mutation (SNP) | VAF 92/173 reads (53%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CEP162 | c.1175C>T p.P392L | Missense Mutation (SNP) | VAF 48/166 reads (29%) | SIFT tolerated (0.32); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CFAP20 | c.391C>T p.Q131* | Nonsense Mutation (SNP) | VAF 194/995 reads (19%) | called by muse, mutect2, varscan2
- CFAP45 | c.731A>T p.E244V | Missense Mutation (SNP) | VAF 79/239 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- CHRD | c.694G>T p.G232C | Missense Mutation (SNP) | VAF 82/240 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- COCH | c.1287C>G p.N429K (on ENST00000216361 / NM_001347720.1; = p.N364K on NM_004086.3) | Missense Mutation (SNP) | VAF 108/477 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CRY1 | c.1017G>T p.W339C | Missense Mutation (SNP) | VAF 83/262 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CUBN | c.10781C>T p.P3594L | Missense Mutation (SNP) | VAF 256/437 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CYFIP1 | c.3551T>A p.L1184H | Missense Mutation (SNP) | VAF 68/204 reads (33%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- DARS2 | c.932C>A p.P311H | Missense Mutation (SNP) | VAF 73/273 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- DNAJC13 | c.724A>T p.K242* | Nonsense Mutation (SNP) | VAF 62/191 reads (32%) | called by muse, mutect2, varscan2
- ECM2 | c.601G>C p.G201R | Missense Mutation (SNP) | VAF 39/138 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- ERMN | c.686G>C p.S229T | Missense Mutation (SNP) | VAF 131/363 reads (36%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- FAM204A | c.631_632del p.K211Efs*8 | Frame Shift Del (DEL) | VAF 105/224 reads (47%) | called by pindel, varscan2
- HDAC8 | c.218del p.D73Vfs*22 | Frame Shift Del (DEL) | VAF 104/187 reads (56%) | called by mutect2, pindel, varscan2
- IL9 | c.235A>G p.T79A | Missense Mutation (SNP) | VAF 41/174 reads (24%) | SIFT tolerated (0.74); PolyPhen benign (0); called by muse, mutect2, varscan2
- ITPRID1 | c.2575C>G p.L859V | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- MAMDC4 | c.3387G>T p.E1129D (on ENST00000445819; = p.E1050D on NM_206920.3) | Missense Mutation (SNP) | VAF 38/121 reads (31%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.525); called by muse, mutect2, varscan2
- OBSCN | c.16406T>A p.L5469Q | Missense Mutation (SNP) | VAF 58/212 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- POGZ | c.2517_2518del p.H840Qfs*23 | Frame Shift Del (DEL) | VAF 41/162 reads (25%) | called by pindel, varscan2
- POLR3H | c.407G>C p.G136A | Missense Mutation (SNP) | VAF 68/204 reads (33%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.474); called by muse, mutect2, varscan2
- PRDM14 | c.1658A>C p.K553T | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.679); called by muse, mutect2, varscan2
- PRKAG2 | c.1403A>C p.K468T | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- PRPF4B | c.2189T>G p.L730* | Nonsense Mutation (SNP) | VAF 13/63 reads (21%) | called by muse, mutect2
- PTH2R | c.1120G>T p.V374L | Missense Mutation (SNP) | VAF 71/214 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- PTPN12 | c.738del p.Y246* | Frame Shift Del (DEL) | VAF 37/127 reads (29%) | called by mutect2, pindel, varscan2
- PTPN4 | c.1814-2_1816delinsTTTTT p.X605_splice | Splice Site (ONP) | VAF 6/54 reads (11%) | called by pindel, varscan2*
- QSER1 | c.1699C>G p.Q567E (on ENST00000399302; = p.Q696E on NM_001076786.3) | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- RAB36 | c.996_999del p.C333Nfs*158 | Frame Shift Del (DEL) | VAF 40/157 reads (25%) | called by mutect2, pindel*, varscan2*
- RAPGEF2 | c.2113T>G p.L705V | Missense Mutation (SNP) | VAF 35/120 reads (29%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- RASGEF1B | c.916A>G p.M306V | Missense Mutation (SNP) | VAF 46/145 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.929); called by muse, mutect2, varscan2
- REPS1 | c.1937A>T p.D646V (on ENST00000450536 / NM_001286611.2; = p.D645V on NM_031922.4) | Missense Mutation (SNP) | VAF 59/253 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- SEMA3C | c.361A>G p.T121A | Missense Mutation (SNP) | VAF 55/169 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- SPESP1 | c.1009_1010del p.M337Vfs*2 | Frame Shift Del (DEL) | VAF 11/49 reads (22%) | called by pindel, varscan2
- TRIM42 | c.915C>A p.D305E | Missense Mutation (SNP) | VAF 131/514 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- UGT1A1 | c.121C>G p.L41V | Missense Mutation (SNP) | VAF 99/290 reads (34%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.718); called by muse, mutect2, varscan2
- USP4 | c.2878A>G p.M960V | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- USP4 | c.2613del p.N872Ifs*19 | Frame Shift Del (DEL) | VAF 62/208 reads (30%) | called by mutect2, pindel, varscan2
- ZNF512B | c.2237A>C p.E746A | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.713); called by muse, mutect2, varscan2
- ZNF554 | c.340T>A p.S114T | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT tolerated (0.74); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- ZNF773 | c.142T>G p.F48V | Missense Mutation (SNP) | VAF 69/238 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- GCKR | c.1347G>A p.L449= | Silent (SNP) | VAF 138/529 reads (26%) | called by muse, mutect2, varscan2
- IGF1R | c.2517C>T p.T839= | Silent (SNP) | VAF 97/310 reads (31%) | called by muse, mutect2, varscan2
- ITGAX | c.2766T>C p.Y922= | Silent (SNP) | VAF 54/287 reads (19%) | called by muse, mutect2, varscan2
- LIPT2 | c.552C>T p.P184= | Silent (SNP) | VAF 124/392 reads (32%) | called by muse, mutect2, varscan2
- NFKB1 | c.198T>C p.H66= (on ENST00000394820 / NM_001382627.1; = p.H67= on NM_003998.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 55/199 reads (28%) | called by muse, mutect2, varscan2
- POM121C | c.1086G>A p.L362= (on ENST00000607367; = p.L120= on NM_001099415.3) | Silent (SNP) | VAF 32/113 reads (28%) | called by muse, mutect2, varscan2
- PPP2R1B | c.1434C>T p.L478= | Silent (SNP) | VAF 22/129 reads (17%) | catalogued as COSV59535286; called by muse, mutect2, varscan2
- PRKACG | c.150G>A p.L50= | Silent (SNP) | VAF 85/297 reads (29%) | catalogued as rs1169559596; called by muse, mutect2, varscan2
- SASS6 | c.981A>G p.L327= | Silent (SNP) | VAF 94/266 reads (35%) | called by muse, mutect2, varscan2
- SH3RF2 | c.1212A>C p.G404= | Silent (SNP) | VAF 56/216 reads (26%) | called by muse, mutect2, varscan2
- SLC28A3 | c.1377C>A p.A459= | Silent (SNP) | VAF 42/161 reads (26%) | called by muse, mutect2, varscan2
- UGT1A7 | c.507C>T p.A169= | Silent (SNP) | VAF 103/324 reads (32%) | catalogued as rs770529421; called by muse, mutect2, varscan2
- AIDA | c.110+32del | Intron (DEL) | VAF 42/130 reads (32%) | called by mutect2, pindel*, varscan2
- CCDC159 | c.567+45G>A | Intron (SNP) | VAF 22/57 reads (39%) | called by muse, mutect2, varscan2
- CCDC88C | c.4699+269G>C | Intron (SNP) | VAF 69/210 reads (33%) | called by muse, mutect2, varscan2
- FHL1 | c.*271G>A | 3'UTR (SNP) | VAF 73/143 reads (51%) | called by muse, mutect2, varscan2
- PLSCR1 | c.*18C>T | 3'UTR (SNP) | VAF 17/104 reads (16%) | called by muse, mutect2, varscan2
- PML | c.1710+43C>T | Intron (SNP) | VAF 127/313 reads (41%) | catalogued as rs1187724212, COSV51445280; called by muse, mutect2, varscan2
- RIN3 | c.-4C>T | 5'UTR (SNP) | VAF 3/12 reads (25%) | catalogued as rs1300942704; called by muse, varscan2
- UQCRB | c.*3846G>C | 3'UTR (SNP) | VAF 24/83 reads (29%) | called by muse, mutect2, varscan2
